Somatic mutation profile of tumor specimen TARGET-20-PARZUU-09A (aliquot TARGET-20-PARZUU-09A-02D) from TARGET case TARGET-20-PARZUU, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.0 years (3,273 days).
Specimen TARGET-20-PARZUU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26ff9e0a-af6d-4933-ba87-e4b50726d2fd.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARZUU-14A (Bone Marrow Normal), aliquot TARGET-20-PARZUU-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b19b739a-5bb5-4ad6-90ba-586e5f824ae3

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: In Frame Del 1, Missense Mutation 1, Frame Shift Ins 1, 3'UTR 1, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2446G>C p.D816H | Missense Mutation (SNP) | VAF 32/196 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs121913506, COSV55386862, COSV55387240, COSV55408330; ClinVar: likely pathogenic / other / pathogenic; called by muse, varscan2
- IKZF1 | c.1138A>T p.K380* | Nonsense Mutation (SNP) | VAF 44/99 reads (44%) | catalogued as COSV58792734; called by muse, mutect2, varscan2
- CCND3 | c.811dup p.R271Pfs*53 | Frame Shift Ins (INS) | VAF 26/60 reads (43%) | called by mutect2, pindel, varscan2
- KIT | c.1255_1257del p.D419del | In Frame Del (DEL) | VAF 27/197 reads (14%) | called by mutect2, pindel, varscan2
- HASPIN | c.129C>T p.F43= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as rs775319727, COSV54001239; called by muse, mutect2, varscan2
- HDAC9 | c.*1088G>T | 3'UTR (SNP) | VAF 94/199 reads (47%) | called by muse, mutect2
